HCMI case HCM-WCMC-0751-C54 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/482c0ee1-5046-4fc7-b284-57923228ca23

Demographics
Sex at birth: female; Year of birth: 1965; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, secretory variant: ICD-O-3 morphology code: 8382/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 54.6 years (19,958 days); AJCC staging edition: 8th; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Lymph node involvement: Negative; Lymphatic invasion present: Yes; Tumor largest dimension diameter: 4.5 cm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 47 days; Days to treatment end: 96 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 1,084 days (3.0 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 452.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.
- TP53 (IHC): Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 53.1 kg; Height: 160 cm; BMI: 21.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-0751-C54-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-0751-C54-01A-S1-HE: Section location: Top; Percent tumor cells: 71; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 25; Percent lymphocyte infiltration: 22; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide HCM-WCMC-0751-C54-01A-S2-HE: Section location: Bottom; Percent tumor cells: 56; Percent tumor nuclei: 72; Percent normal cells: 0; Percent necrosis: 9; Percent stromal cells: 35; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample HCM-WCMC-0751-C54-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0751-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 12.
